Somatic mutation profile of tumor specimen MMRF_2112_1_BM_CD138pos (aliquot MMRF_2112_1_BM_CD138pos_T1_KHS5U_L08656) from MMRF case MMRF_2112, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 52.0 years (19,011 days).
Specimen MMRF_2112_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a8632ab0-df5e-42e8-b2a1-b9f4baa04489.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2112_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2112_1_PB_Whole_C2_KHS5U_L08657; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ed670209-466a-49a5-9b5a-3a5439f07517

The open-access MAF lists 177 somatic variants for this specimen: 80 protein-altering or splice-affecting, 19 silent, 78 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 67, 3'UTR 44, Intron 23, Silent 19, Nonsense Mutation 6, 5'UTR 5, Splice Site 4, RNA 3, 3'Flank 2, Frame Shift Del 2, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIM1 | c.72G>C p.K24N | Missense Mutation (SNP) | VAF 61/138 reads (44%) | hotspot (GDC flag); SIFT tolerated (0.48); PolyPhen benign (0.062); catalogued as COSV65164988, COSV65166078, COSV65166386; called by muse, mutect2, varscan2
- ANKRD30A | c.3425A>T p.K1142M (on ENST00000611781; = p.K1086M on NM_052997.2) | Missense Mutation (SNP) | VAF 12/211 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64604431; called by muse, mutect2
- ARHGAP18 | c.616+2T>G p.X206_splice | Splice Site (SNP) | VAF 50/123 reads (41%) | catalogued as COSV100936069; called by muse, mutect2, varscan2
- ARMC10 | c.814G>A p.V272I | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.136); catalogued as rs142543653; called by muse, mutect2
- B4GALNT4 | c.1442G>A p.R481H | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.069); catalogued as rs1229717313; called by muse, mutect2, varscan2
- CDH10 | c.1494T>A p.C498* | Nonsense Mutation (SNP) | VAF 127/227 reads (56%) | catalogued as COSV52589098; called by muse, mutect2, varscan2
- COL6A3 | c.5635G>A p.G1879S | Missense Mutation (SNP) | VAF 78/186 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.021); catalogued as rs760603443, COSV55080149; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- DNAH5 | c.6448C>T p.H2150Y | Missense Mutation (SNP) | VAF 14/231 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54216402; called by muse, mutect2
- DST | c.12628C>T p.R4210C (on ENST00000361203 / NM_001374722.1; = p.R1798C on NM_015548.5) | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1000717078; called by muse, mutect2, varscan2
- EDEM3 | c.132G>A p.M44I | Missense Mutation (SNP) | VAF 91/635 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as COSV100544804; called by muse, mutect2, varscan2
- FBLL1 | c.562C>T p.H188Y | Missense Mutation (SNP) | VAF 69/186 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs754856758; called by muse, mutect2, varscan2
- FGF14 | c.163G>A p.G55S | Missense Mutation (SNP) | VAF 143/217 reads (66%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs1411679794, COSV65941276; called by muse, mutect2, varscan2
- FHDC1 | c.2857G>A p.E953K | Missense Mutation (SNP) | VAF 51/98 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.349); catalogued as rs150371797; called by muse, mutect2, varscan2
- GRWD1 | c.1021A>G p.K341E | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.101); catalogued as rs1436792498; called by muse, mutect2, varscan2
- IGHV2-70 | c.293A>C p.Q98P | Missense Mutation (SNP) | VAF 52/58 reads (90%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs373048671; called by muse, varscan2
- IGHV2-70 | c.48G>A p.W16* | Nonsense Mutation (SNP) | VAF 46/54 reads (85%) | catalogued as rs375927713; called by muse, mutect2, varscan2
- IGLV7-46 | c.152G>A p.G51D | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs370564779; called by muse, mutect2, varscan2
- ITGAE | c.1020+1G>T p.X340_splice | Splice Site (SNP) | VAF 30/63 reads (48%) | catalogued as rs770100518, COSV53999403; called by muse, mutect2, varscan2
- JMJD8 | c.225+1G>A p.X75_splice | Splice Site (SNP) | VAF 29/86 reads (34%) | catalogued as rs112507487, COSV50196698; called by muse, mutect2, varscan2
- LAYN | c.155T>C p.V52A (on ENST00000375615 / NM_001258390.1; = p.V44A on NM_178834.5) | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.787); catalogued as COSV100986274; called by muse, mutect2, varscan2
- LCMT2 | c.527G>A p.G176E | Missense Mutation (SNP) | VAF 70/147 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs138729211; called by muse, mutect2, varscan2
- MAGED1 | c.203C>T p.S68L | Missense Mutation (SNP) | VAF 65/68 reads (96%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as rs782818810, COSV58515197; called by muse, mutect2, varscan2
- METTL2A | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 54/233 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV100274401; called by muse, mutect2, varscan2
- MYO18B | c.5506G>A p.V1836M | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as rs1406026123; called by muse, mutect2
- PDE11A | c.271G>A p.G91R | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs866762484; called by muse, mutect2, varscan2
- PRODH2 | c.638G>A p.R213Q (on ENST00000301175; = p.R137Q on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 61/208 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.111); catalogued as rs527312733, COSV99995611; called by muse, mutect2, varscan2
- SEMA3F | c.906C>T p.N302= | Splice Region (SNP) | VAF 27/152 reads (18%) | catalogued as rs776160589; called by muse, mutect2, varscan2
- SLITRK4 | c.11G>A p.W4* | Nonsense Mutation (SNP) | VAF 82/97 reads (85%) | catalogued as COSV100567516; called by muse, mutect2, varscan2
- TAAR8 | c.143G>T p.G48V | Missense Mutation (SNP) | VAF 128/307 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1405317201; called by muse, mutect2, varscan2
- TNPO1 | c.1291G>A p.A431T | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.755); catalogued as COSV61521609; called by muse, mutect2, varscan2
- ZFR2 | c.1723G>A p.A575T | Missense Mutation (SNP) | VAF 51/165 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs558302396; called by muse, mutect2, varscan2
- ABCC1 | c.3858_3871delinsA p.S1286Rfs*47 | Frame Shift Del (DEL) | VAF 20/176 reads (11%) | called by pindel, varscan2*
- ADAMTS19 | c.1031T>G p.V344G | Missense Mutation (SNP) | VAF 96/288 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- AKAP3 | c.1373T>G p.L458R | Missense Mutation (SNP) | VAF 130/302 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ALX1 | c.226+2T>G p.X76_splice | Splice Site (SNP) | VAF 6/9 reads (67%) | called by muse, mutect2
- ANKRD17 | c.6433G>A p.A2145T | Missense Mutation (SNP) | VAF 54/140 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ATP2B1 | c.1625G>T p.G542V | Missense Mutation (SNP) | VAF 15/169 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CD163L1 | c.450A>C p.E150D | Missense Mutation (SNP) | VAF 112/237 reads (47%) | SIFT tolerated (0.61); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CLTA | c.472A>G p.K158E | Missense Mutation (SNP) | VAF 20/288 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- CPAMD8 | c.5024G>C p.R1675P (on ENST00000651564; = p.R1628P on NM_015692.5) | Missense Mutation (SNP) | VAF 36/147 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- CRACD | c.662G>A p.R221K | Missense Mutation (SNP) | VAF 73/150 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DDX3X | c.1448T>G p.L483R (on ENST00000399959; = p.L484R on NM_001356.5) | Missense Mutation (SNP) | VAF 40/46 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DGKI | c.1402G>A p.A468T | Missense Mutation (SNP) | VAF 72/241 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DGKK | c.958A>C p.N320H | Missense Mutation (SNP) | VAF 42/49 reads (86%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- EIF4E2 | c.404G>A p.W135* | Nonsense Mutation (SNP) | VAF 19/164 reads (12%) | called by muse, mutect2, varscan2
- ELN | c.1091T>G p.V364G | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); called by muse, mutect2
- ELOB | c.173G>A p.G58D | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- FOXN3 | c.745G>A p.D249N (on ENST00000261302; = p.V249I on NM_005197.4) | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GFI1 | c.775A>T p.K259* | Nonsense Mutation (SNP) | VAF 17/39 reads (44%) | called by muse, mutect2, varscan2
- GREB1L | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- GREB1L | c.3691G>A p.V1231M | Missense Mutation (SNP) | VAF 25/187 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- H2BC21 | c.58A>G p.T20A | Missense Mutation (SNP) | VAF 60/358 reads (17%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- H2BC9 | c.142C>G p.Q48E | Missense Mutation (SNP) | VAF 50/168 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- HAUS6 | c.2458A>G p.R820G | Missense Mutation (SNP) | VAF 146/301 reads (49%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IER2 | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- IGHV3-53 | c.293A>T p.Y98F | Missense Mutation (SNP) | VAF 96/112 reads (86%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.282); called by muse, varscan2
- ING2 | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.6); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- IRF4 | c.316G>T p.D106Y | Missense Mutation (SNP) | VAF 60/179 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KMT2C | c.14312C>T p.S4771F | Missense Mutation (SNP) | VAF 17/278 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- LHFPL5 | c.194T>C p.F65S | Missense Mutation (SNP) | VAF 24/407 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2
- MACF1 | c.21275G>T p.G7092V (on ENST00000372915; = p.G5137V on NM_012090.5) | Missense Mutation (SNP) | VAF 90/226 reads (40%) | called by muse, mutect2, varscan2
- MAMDC2 | c.557C>T p.P186L | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- MLXIPL | c.1853G>A p.S618N | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- NTRK3 | c.330C>G p.I110M | Missense Mutation (SNP) | VAF 8/204 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- PCDHA2 | c.732_735del p.S245Ffs*4 | Frame Shift Del (DEL) | VAF 115/227 reads (51%) | called by mutect2, pindel, varscan2
- PDHA2 | c.1152T>G p.F384L | Missense Mutation (SNP) | VAF 150/308 reads (49%) | SIFT tolerated (0.86); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RNF138 | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RNF214 | c.196C>T p.H66Y | Missense Mutation (SNP) | VAF 17/244 reads (7%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.143); called by muse, mutect2
- SARAF | c.328A>G p.T110A | Missense Mutation (SNP) | VAF 22/900 reads (2%) | SIFT deleterious (0.03); PolyPhen benign (0.192); called by muse, mutect2
- SLC30A5 | c.1558C>T p.H520Y | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SNX30 | c.194C>T p.T65I | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SP100 | c.409T>G p.L137V | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SP140 | c.1866G>A p.W622* | Nonsense Mutation (SNP) | VAF 30/138 reads (22%) | called by muse, mutect2, varscan2
- STKLD1 | c.190G>A p.D64N | Missense Mutation (SNP) | VAF 43/81 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SYBU | c.1636A>G p.R546G (on ENST00000276646 / NM_001099754.2; = p.R545G on NM_017786.6) | Missense Mutation (SNP) | VAF 74/164 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- TLN2 | c.734C>T p.A245V | Missense Mutation (SNP) | VAF 70/283 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- TRIM77 | c.1061T>G p.V354G | Missense Mutation (SNP) | VAF 104/244 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- UBR4 | c.3848C>T p.S1283F | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- USO1 | c.1688A>T p.K563M | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- ZNF678 | c.1395A>C p.E465D | Missense Mutation (SNP) | VAF 52/323 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- BAIAP2L1 | c.30G>A p.R10= | Silent (SNP) | VAF 47/100 reads (47%) | catalogued as rs1204757575, COSV50059438; called by muse, mutect2, varscan2
- C8orf34 | c.1185T>G p.T395= | Silent (SNP) | VAF 62/137 reads (45%) | catalogued as COSV57397098; called by muse, mutect2, varscan2
- COL16A1 | c.1905C>T p.C635= | Silent (SNP) | VAF 14/151 reads (9%) | catalogued as rs776776035; called by muse, mutect2
- CREB3L2 | c.213G>T p.T71= | Silent (SNP) | VAF 85/203 reads (42%) | catalogued as COSV57797338; called by muse, mutect2, varscan2
- EGR1 | c.96C>T p.Y32= | Silent (SNP) | VAF 122/250 reads (49%) | catalogued as rs777179772; called by muse, varscan2
- FOXRED1 | c.615G>A p.V205= | Silent (SNP) | VAF 12/128 reads (9%) | called by muse, mutect2
- GARRE1 | c.573G>A p.P191= | Silent (SNP) | VAF 44/154 reads (29%) | catalogued as rs778495001; called by muse, mutect2, varscan2
- IGLV1-40 | c.102G>T p.G34= | Silent (SNP) | VAF 43/99 reads (43%) | called by muse, varscan2
- LIMS2 | c.891G>A p.V297= (on ENST00000355119 / NM_001161403.3; = p.V321= on NM_017980.4) | Silent (SNP) | VAF 84/196 reads (43%) | catalogued as rs1364737363; called by muse, mutect2, varscan2
- MAMDC4 | c.2193C>T p.L731= (on ENST00000445819; = p.L652= on NM_206920.3) | Silent (SNP) | VAF 15/114 reads (13%) | called by muse, mutect2, varscan2
- OR10C1 | c.699G>A p.A233= (on ENST00000622521; = p.A231= on NM_013941.3) | Silent (SNP) | VAF 123/431 reads (29%) | catalogued as rs772606781; called by muse, mutect2
- RAPGEF2 | c.73C>T p.L25= | Silent (SNP) | VAF 22/49 reads (45%) | called by muse, mutect2, varscan2
- SSTR5 | c.966C>T p.R322= | Silent (SNP) | VAF 16/190 reads (8%) | called by muse, mutect2
- TDRD15 | c.2028A>C p.V676= | Silent (SNP) | VAF 35/78 reads (45%) | called by muse, mutect2, varscan2
- THBS2 | c.459C>A p.T153= | Silent (SNP) | VAF 39/90 reads (43%) | called by muse, mutect2, varscan2
- TLR5 | c.1167G>A p.L389= | Silent (SNP) | VAF 80/332 reads (24%) | called by muse, mutect2, varscan2
- TRIM69 | c.957C>T p.C319= (on ENST00000329464 / NM_182985.5; = p.C160= on NM_080745.5) | Silent (SNP) | VAF 17/107 reads (16%) | called by muse, mutect2, varscan2
- ZNF136 | c.1173T>C p.P391= | Silent (SNP) | VAF 54/185 reads (29%) | called by muse, mutect2, varscan2
- ZNF81 | c.1971C>T p.R657= | Silent (SNP) | VAF 18/153 reads (12%) | called by muse, mutect2, varscan2
- ADAMTS6 | c.*1418A>C | 3'UTR (SNP) | VAF 104/176 reads (59%) | called by muse, mutect2, varscan2
- ADCY10 | c.3310-474C>T | Intron (SNP) | VAF 65/300 reads (22%) | called by muse, mutect2, varscan2
- AL589666.1 | c.*50+4081C>T | Intron (SNP) | VAF 12/140 reads (9%) | called by muse, mutect2
- ANKRD50 | c.-723C>T | 5'UTR (SNP) | VAF 23/59 reads (39%) | called by muse, mutect2, varscan2
- AQP5 | c.*347C>A | 3'UTR (SNP) | VAF 66/120 reads (55%) | called by muse, mutect2, varscan2
- ARL4C | c.*943G>A | 3'UTR (SNP) | VAF 16/204 reads (8%) | catalogued as rs757575466; called by muse, mutect2
- ARMC10P1 | n.637G>A | RNA (SNP) | VAF 30/65 reads (46%) | catalogued as rs1011544400; called by muse, mutect2, varscan2
- ATL2 | c.*201G>A | 3'UTR (SNP) | VAF 10/52 reads (19%) | called by muse, mutect2, varscan2
- ATP8B1 | c.181+1304A>G | Intron (SNP) | VAF 34/74 reads (46%) | called by muse, mutect2, varscan2
- C5orf64 | n.513-43884C>T | Intron (SNP) | VAF 7/22 reads (32%) | called by mutect2, varscan2
- CADM2 | chr3:86068269 C>A | 3'Flank (SNP) | VAF 6/81 reads (7%) | called by muse, mutect2
- CCDC71L | c.*2591A>C | 3'UTR (SNP) | VAF 9/144 reads (6%) | called by muse, mutect2
- CDK20 | c.*1020A>C | 3'UTR (SNP) | VAF 27/77 reads (35%) | called by muse, mutect2, varscan2
- CDK2AP1 | c.56-232G>T | Intron (SNP) | VAF 16/224 reads (7%) | called by muse, mutect2
- CIDEC | c.53+66A>G | Intron (SNP) | VAF 77/163 reads (47%) | called by muse, mutect2, varscan2
- CNGA3 | c.*831T>G | 3'UTR (SNP) | VAF 46/105 reads (44%) | called by muse, mutect2, varscan2
- DAGLA | c.*149G>A | 3'UTR (SNP) | VAF 41/107 reads (38%) | catalogued as rs894764361, COSV99944473; called by muse, mutect2, varscan2
- DCAF17 | c.*518T>C | 3'UTR (SNP) | VAF 31/93 reads (33%) | called by muse, mutect2, varscan2
- DCLK1 | c.941-1186C>T | Intron (SNP) | VAF 24/30 reads (80%) | called by muse, mutect2
- EIF1AX | c.*758A>C | 3'UTR (SNP) | VAF 58/142 reads (41%) | called by muse, mutect2, varscan2
- ELAC2 | c.739-17T>C | Intron (SNP) | VAF 10/153 reads (7%) | called by muse, mutect2
- FABP7 | c.348+440T>A | Intron (SNP) | VAF 13/92 reads (14%) | called by muse, mutect2, varscan2
- FAM20C | c.864-17869A>G | Intron (SNP) | VAF 4/100 reads (4%) | called by muse, mutect2
- FCGR1B | chr1:121097332 G>T | 3'Flank (SNP) | VAF 20/49 reads (41%) | called by muse, mutect2, varscan2
- FLRT3 | c.*2513A>T | 3'UTR (SNP) | VAF 6/12 reads (50%) | called by muse, mutect2, varscan2
- FYTTD1 | c.*269G>T | 3'UTR (SNP) | VAF 41/80 reads (51%) | called by muse, mutect2, varscan2
- GABRB2 | c.*5211C>T | 3'UTR (SNP) | VAF 14/197 reads (7%) | called by muse, mutect2
- GPM6A | c.*1325C>T | 3'UTR (SNP) | VAF 38/72 reads (53%) | called by muse, mutect2, varscan2
- HSPG2 | c.*832G>A | 3'UTR (SNP) | VAF 27/166 reads (16%) | catalogued as rs945155682; called by muse, mutect2, varscan2
- IGF2 | c.*17T>C | 3'UTR (SNP) | VAF 42/104 reads (40%) | called by muse, mutect2, varscan2
- IGLC3 | c.*2T>A | 3'UTR (SNP) | VAF 68/74 reads (92%) | called by muse, mutect2, varscan2
- IGLV1-40 | c.-26A>C | 5'UTR (SNP) | VAF 29/58 reads (50%) | catalogued as rs777625788; called by muse, varscan2
- KLF9 | c.-704G>C | 5'UTR (SNP) | VAF 12/166 reads (7%) | called by muse, mutect2
- LINC02692 | n.580C>T | RNA (SNP) | VAF 13/94 reads (14%) | catalogued as rs753712924; called by muse, mutect2, varscan2
- MAP9 | c.*410T>C | 3'UTR (SNP) | VAF 6/124 reads (5%) | called by muse, mutect2
- MIB1 | c.*517T>A | 3'UTR (SNP) | VAF 63/149 reads (42%) | called by muse, mutect2, varscan2
- MYCN | c.*83T>A | 3'UTR (SNP) | VAF 52/242 reads (21%) | called by muse, mutect2, varscan2
- MYCN | c.*84G>A | 3'UTR (SNP) | VAF 52/242 reads (21%) | called by muse, mutect2, varscan2
- MYRF | c.*440A>T | 3'UTR (SNP) | VAF 11/57 reads (19%) | called by muse, mutect2
- NDUFAF4 | c.*436G>C | 3'UTR (SNP) | VAF 108/229 reads (47%) | called by muse, mutect2, varscan2
- NME3 | c.-98C>A | 5'UTR (SNP) | VAF 12/40 reads (30%) | catalogued as rs911050323; called by muse, mutect2, varscan2
- NTM | c.934+291G>T | Intron (SNP) | VAF 28/65 reads (43%) | called by muse, mutect2, varscan2
- NUCKS1 | c.*2804T>A | 3'UTR (SNP) | VAF 17/106 reads (16%) | called by muse, mutect2, varscan2
- OTULINL | c.*1521A>T | 3'UTR (SNP) | VAF 22/106 reads (21%) | called by muse, mutect2, varscan2
- PIK3C2B | c.934-1560A>G | Intron (SNP) | VAF 28/141 reads (20%) | called by muse, mutect2, varscan2
- PIPSL | n.1768G>A | RNA (SNP) | VAF 15/138 reads (11%) | called by muse, mutect2, varscan2
- PRR18 | c.*590C>T | 3'UTR (SNP) | VAF 39/78 reads (50%) | catalogued as rs918223971; called by muse, mutect2, varscan2
- PSENEN | c.-9A>T | 5'UTR (SNP) | VAF 58/114 reads (51%) | called by muse, varscan2
- PSMB4 | c.348-77T>A | Intron (SNP) | VAF 7/25 reads (28%) | called by muse, varscan2
- PTGDS | c.551-74G>A | Intron (SNP) | VAF 26/235 reads (11%) | called by muse, mutect2, varscan2
- PTPRF | c.*370C>A | 3'UTR (SNP) | VAF 54/110 reads (49%) | called by muse, mutect2, varscan2
- RBM46 | c.*13C>T | 3'UTR (SNP) | VAF 140/327 reads (43%) | catalogued as rs1367009163; called by muse, mutect2, varscan2
- RPL27A | c.144-244T>G | Intron (SNP) | VAF 20/77 reads (26%) | called by muse, mutect2, varscan2
- RPRD1B | c.*75C>T | 3'UTR (SNP) | VAF 60/129 reads (47%) | called by muse, mutect2, varscan2
- RUNX1 | c.*2136A>G | 3'UTR (SNP) | VAF 71/143 reads (50%) | called by muse, mutect2, varscan2
- RXRG | c.49+7838A>T | Intron (SNP) | VAF 5/42 reads (12%) | called by muse, mutect2
- SCYL2 | c.1509+161G>A | Intron (SNP) | VAF 11/69 reads (16%) | called by muse, mutect2, varscan2
- SDS | c.*2G>A | 3'UTR (SNP) | VAF 114/255 reads (45%) | catalogued as rs760149546; called by muse, mutect2, varscan2
- SEMA3A | c.*844G>A | 3'UTR (SNP) | VAF 40/132 reads (30%) | called by muse, mutect2, varscan2
- SHROOM3 | c.5198+113C>T | Intron (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
- SI | c.*314T>G | 3'UTR (SNP) | VAF 13/28 reads (46%) | called by muse, mutect2, varscan2
- SLC22A3 | c.*878T>C | 3'UTR (SNP) | VAF 40/43 reads (93%) | called by muse, mutect2, varscan2
- SLC26A2 | c.*3199C>T | 3'UTR (SNP) | VAF 16/177 reads (9%) | catalogued as rs1261107608; called by muse, mutect2
- SLCO4C1 | c.*1749G>A | 3'UTR (SNP) | VAF 25/812 reads (3%) | called by muse, mutect2
- SMTNL2 | c.*150C>T | 3'UTR (SNP) | VAF 31/64 reads (48%) | called by muse, mutect2, varscan2
- SP3 | c.*2128A>C | 3'UTR (SNP) | VAF 29/61 reads (48%) | called by muse, mutect2, varscan2
- SPCS3 | c.*2665A>C | 3'UTR (SNP) | VAF 8/99 reads (8%) | called by muse, mutect2
- SRP72 | c.1641-74T>A | Intron (SNP) | VAF 17/32 reads (53%) | called by muse, mutect2, varscan2
- SV2C | c.*3968_*3972del | 3'UTR (DEL) | VAF 22/70 reads (31%) | called by mutect2, pindel, varscan2
- TMSB4X | chrX:12975349 G>A | 5'Flank (SNP) | VAF 79/86 reads (92%) | catalogued as COSV104432400; called by muse, mutect2, varscan2
- TRIM3 | c.*116G>A | 3'UTR (SNP) | VAF 20/173 reads (12%) | called by muse, mutect2, varscan2
- TSPAN19 | c.678+67G>C | Intron (SNP) | VAF 9/19 reads (47%) | called by muse, mutect2, varscan2
- UCP1 | c.*107T>C | 3'UTR (SNP) | VAF 52/126 reads (41%) | called by muse, mutect2, varscan2
- USH2A | c.*1085G>A | 3'UTR (SNP) | VAF 36/123 reads (29%) | called by muse, mutect2, varscan2
- VAPA | c.591+65G>A | Intron (SNP) | VAF 34/87 reads (39%) | called by muse, mutect2, varscan2
- VCP | c.1482+22T>G | Intron (SNP) | VAF 25/116 reads (22%) | called by muse, mutect2, varscan2
- ZRSR2 | c.42-28_42-10del | Intron (DEL) | VAF 13/32 reads (41%) | called by mutect2, pindel*, varscan2*
- ZYG11B | c.*997C>T | 3'UTR (SNP) | VAF 24/43 reads (56%) | called by muse, mutect2, varscan2
